Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAH9, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAH9-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 5,0 cm; no angio-invasion;no invasion in rete-testis;
no invasion of tunica albuginea.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O-3
Seminoma NOS 9061/3
Site (R) Testis NOS C62.9
p10 3/7/14

Source: NCI Genomic Data Commons file 35b78971-8bda-4d67-80c7-5cfd807929e4 (TCGA-2G-AAH9-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).